Gene-level copy-number profile of tumor specimen TCGA-UY-A78L-01A from TCGA case TCGA-UY-A78L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,717 days).
Specimen TCGA-UY-A78L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.43fbf86a-a9e3-446e-b1ca-83f64e45cf06.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A78L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f092e9cd-75dd-4b82-8def-f3f03abdee9d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 495; copy number 2: 5,325; copy number 3: 25,631; copy number 4: 17,295; copy number 5: 7,939; copy number 6: 1,944; copy number 7: 378; copy number 10: 96; copy number 17: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A78L-01A-12D-A338-01): tumor purity 0.49, ploidy 3.28, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,182 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:162,316,852–167,427,345, 96 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:234,957,231–248,919,946, 332 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 17 (broad region; genes not listed).
- chr22:33,104,330–33,145,861, 1 gene, copy number 7 (within-gene range 5–7): LINC01640.
- chr22:33,137,140–36,028,824, 43 genes, copy number 7: Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1.

Autosomal genes at a single copy (total copy number 1): 495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
